Surgical pathology report (de-identified scan), TCGA case TCGA-06-0238, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0238-01A (Primary Tumor).

[page 1 of 2]
TCGA-06-0238

Surgical Pathology Report

CLINICAL HISTORY

[REDACTED] with headaches for one month has a left temporal necrotic and enhancing lesion, with appreciable edema and mass effect.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, excision biopsy
B: Brain, left temporal, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, left temporal, excision: Glioblastoma.
See Comment.

COMMENT

Both specimens contain glioblastoma. The neoplasm has numerous giant cells, mitotic activity, focal necrosis, and prominent microvascular cellular proliferation that focally has a sarcomatoid pattern.

Special stains to better characterize the neoplasm have been requested and will be reported as an addendum.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE - No evidence of methylated MGMT promoter is detected.

Results-Comments

Received were paraffin curls labeled [REDACTED].

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

[page 2 of 2]
[REDACTED]

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

Interpretation

Brain, Immunohistochemistry: MIB-1 proliferation index 11%.
See Results and Comment (below).

Results-Comments

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates glial fibrillogenesis by the neoplastic cells. The synaptophysin and NeuN depict neurons in the zone where the neoplasm infiltrates cerebral cortex. The NFP is negative. The CD34 denotes small vessels with microvascular cellular proliferation. With the MIB-1 there is a proliferation index of about 11% in the more active areas. The sarcomatoid areas are GFAP negative and virtually devoid of vessels. SPECIAL STAIN: The Snook's reticulum demonstrates absent reticulin within the sarcomatoid areas.

Comment: These results are consistent with a high histological grade astrocytic tumor, without a neuronal component, i.e. a glioblastoma. The focal histological sarcomatoid areas appear to be a new, undifferentiated clone of non-sarcomatous neoplastic cells.

[REDACTED]

INTRA-OPERATIVE CONSULTATION

A. Brain, excision biopsy, touch prep and smears: Glioma, high histological grade (suggestive of giant cell glioblastoma).

[REDACTED]

GROSS DESCRIPTION

A.

Received fresh, three fragments, 0.35 cm. in aggregate. Firm, lobular, pinkish-gray. In total, A1.

B.

SPECIMEN: Tumor.

FIXATIVE: None.

GENERAL: Received is a 0.6 x 0.4 x 0.2 cm. irregular portion of tan-pink

[REDACTED]

Source: NCI Genomic Data Commons file 69312d7f-41a6-45d8-b09b-ddb261d5a1b6 (TCGA-06-0238.2A19D86E-BEA6-4892-9FA4-8F13FDFA9FA4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).